CCDI case PBCUUB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/94c16d92-a4f3-4f53-a461-07f71e6b2d32

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E061T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E062Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1CW3: Tissue type: Tumor; Specimen type: Solid Tissue.
